Surgical pathology report (de-identified scan), TCGA case TCGA-XG-A823, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site BLN UT Southwestern Medical Center at Dallas, specimen TCGA-XG-A823-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Clinical History

with SDHD mutation and multiple pheo/paraganglioma left adrenalectomy at age
Pheochromocytoma.

Preoperative Diagnosis

Pheochromocytoma

ICD-O-3
Pheochromocytoma NOS 8700/3
Site @ Adrenal gland NOS C74.9
JWS 4/4/14

Gross Description

Specimen: A. Right paraganglioma

Procedure: Excision

Fixative: Formalin

Patient Identifiers:

Cassette case number is [REDACTED] for patient [REDACTED]

Container case number is [REDACTED]

Container label is for [REDACTED] and the MRN is [REDACTED]

Requisition form is for [REDACTED] and the MRN is [REDACTED]

Specimen Size and Pathologic Findings: The specimen consists of a red-tan soft tissue fragment with a focal area of tan-yellow soft tissue, measuring 1.1 x 0.7 x 0.3 cm. A frozen section is performed on the specimen.

Section Key: The specimen is submitted entirely in A1.

Specimen: B. Paraganglioma

Procedure: Excision

Fixative: Formalin

Patient Identifiers:

Cassette case number is [REDACTED] for patient [REDACTED]

Container case number is [REDACTED]

Container label is for [REDACTED] and the MRN is [REDACTED]

Requisition form is for [REDACTED] and the MRN is [REDACTED]

Specimen Size and Pathologic Findings: The specimen consists of a 2.5 x 2.0 x 0.8 cm irregularly shaped, tan-pink and yellow soft tissue fragment. The specimen contains two ovoid tan-pink nodules measuring 1.0 cm each and a 1.3 x 1.3 x 0.6 cm tan-pink partial fragment of possible lymph node. The remainder of the specimen consists of adipose tissue.

Section Key: The specimen is submitted as follows:

B1 & B2: one nodule, each bisected

B3: partial fragment of lymph node, bisected

B4: adipose tissue

Specimen: C. Right adrenal ✓

Procedure: Excision

Fixative: Formalin

Patient Identifiers:

Cassette case number is [REDACTED] for patient [REDACTED]

Container case number is [REDACTED]

Container label is for [REDACTED] and the [REDACTED]

Requisition form is for [REDACTED] and the [REDACTED]

Specimen Size and Pathologic Findings: The specimen consists of a 42 gram, 5.5 x 4.3 x 3.5 cm

*
TCGA
tumor
Submitted

ICDAA Discrepancy		
Asynchronous Primary Nodules		

[page 2 of 2]
adrenal gland removed with 2.5 cm of periglandular adipose tissue. There is a 2.5 x 2.0 cm surgical defect which is inked black (this area corresponds to the area of tumor procurement per the surgeon and does not represent a true surgical margin). The specimen is serially sectioned revealing a 2.2 x 2.5 x 2.5 cm nodule with sharp, well demarcation from the adrenal gland. The nodule has a variegated, tan-pink and red cross section with cystic areas and focal areas of calcification and necrosis. The remaining adrenal gland has a triangular shape measuring 3.5 x 1.0 x 2.5 cm with a tan-pink medulla and yellow cortices.

Section Key: The specimen is submitted as follows:

C1: area of tumor procurement

C2-C6: representative sections of the nodule

Intraoperative Consult Diagnosis

Frozen section diagnosis by _____ on _____ is "RIGHT PARAGANGLIOMA: PARAGANGLIOMA."

Microscopic Diagnosis

A. Right paraganglioma (excision):

-Paraganglioma.

-Frozen section diagnosis confirmed.

B. Paraganglioma (excision):

-Paraganglioma.

-Four benign lymph nodes.

C. Right adrenal (adrenalectomy):

-Pheochromocytoma, 2.5 cm, completely excised.

Comment:

This case has been reviewed by _____ and _____ who agree with the diagnosis.

I have personally reviewed the diagnostic material and this report represents my interpretation.

Electronic Signature

Source: NCI Genomic Data Commons file c9fbd211-43ab-4a79-a1bc-114a6f9480a3 (TCGA-XG-A823.D4647CF2-A0D5-49BF-943D-CE9A8A314874.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).